Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GZ-01A (Primary Tumor).

History Case Pathology Report Department of Pathology,

DOB:
Physician

Sex: F

Received: _____

Pathologist: _____

Case type: Surgical History

Accession: _____

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) TISSUE FROM THYROID RULE OUT PARATHYROID:
Lymphoid tissue, non-parathyroid.
- (B) THYROID, STITCH ON RIGHT LOBE:
PAPILLARY CARCINOMA, LEFT LOBE, MEASURING 1.8 CM.
PRESENCE OF VASCULAR INVASION WITH A FOCUS OF INTRATHYROIDAL
METASTASIS (LEFT LOBE) (< THAN 1.0 MM).
Margins of resection free of tumor.
Two capsular lymph nodes, (left) no tumor present.
Two benign parathyroid glands (right).

1CD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
11/30/11

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

- (A) TISSUE FROM THYROID RULE OUT PARATHYROID - Consists of a 0.2 x 0.2 x 0.2 cm tan-pink portion of soft tissue. The entire specimen is submitted for frozen section diagnosis in A.
- (B) THYROID, STITCH IS ON RIGHT LOBE - A total thyroidectomy, black suture is present at the designated positions. The right lobe measures 5.5 x 3.0 x 1.2 cm, the left lobe measures 5.3 x 2.8 x 1.4 cm. There is minimal isthmus tissue. Within the left upper lobe of thyroid, there is a 1.8 x 1.8 x 1.6 cm well-circumscribed, white-tan firm nodule. The tumor is approaching to the capsular surface. No other gross lesions are identified. The specimen is entirely submitted.

INK CODE: Capsular surface is inked black.

SECTION CODE: B1-B12, left thyroid lobe; B6, B8, B9 contains tumor;
B13-B20, right thyroid lobe.

SNOMED CODES

M-80503 T-B6000

Source: NCI Genomic Data Commons file 703a7ef3-32d6-4799-8a0e-fc2114ee9867 (TCGA-EL-A3GZ.08E1BDE1-35B6-4F04-BEC1-D3FCC9A2A9CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).